Somatic mutation profile of tumor specimen TCGA-GN-A8LL-06A (aliquot TCGA-GN-A8LL-06A-21D-A372-08) from TCGA case TCGA-GN-A8LL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.0 years (25,209 days).
Specimen TCGA-GN-A8LL-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7a10612-c0cc-42cb-9087-cb8294aa7733.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GN-A8LL-10A (Blood Derived Normal), aliquot TCGA-GN-A8LL-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd7d41b2-06d3-4f97-ba23-81371b37fc34

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 14, Frame Shift Del 2, Splice Region 1, 3'Flank 1, Nonsense Mutation 1, In Frame Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.1457T>C p.L486P | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99717404; called by muse, mutect2, varscan2
- AEBP1 | c.3393_3398del p.K1133_E1134del | In Frame Del (DEL) | VAF 14/20 reads (70%) | catalogued as rs752781581; called by mutect2, varscan2
- BMP1 | c.2701G>A p.G901S | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.229); catalogued as rs769359150, COSV100114478; called by muse, mutect2, varscan2
- CDKL3 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.261); catalogued as COSV99527486; called by muse, mutect2, varscan2
- CENPB | c.1572T>G p.D524E | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV100713230; called by muse, mutect2, varscan2
- CHERP | c.166T>C p.Y56H | Missense Mutation (SNP) | VAF 140/218 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99549913; called by muse, mutect2, varscan2
- CNTNAP4 | c.2248A>C p.T750P | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100269073; called by muse, mutect2, varscan2
- CTTNBP2 | c.3296T>C p.V1099A | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99352756; called by muse, mutect2, varscan2
- DDX60 | c.4292A>C p.N1431T | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV101190207; called by muse, mutect2, varscan2
- DNAH9 | c.7830C>A p.F2610L | Missense Mutation (SNP) | VAF 186/425 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99303449; called by muse, varscan2
- DTNA | c.545T>C p.F182S | Missense Mutation (SNP) | VAF 17/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99310497; called by muse, mutect2
- FOCAD | c.1196A>T p.K399M | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV100619943; called by muse, mutect2, varscan2
- FPR1 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV100493899; called by muse, mutect2, varscan2
- GALNT5 | c.680C>A p.P227Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); catalogued as rs1203162366, COSV52041016, COSV99374760; called by muse, mutect2, varscan2
- HSPA12B | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99653775; called by muse, mutect2, varscan2
- IL9R | c.1186G>C p.G396R | Missense Mutation (SNP) | VAF 69/83 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99729130, COSV99729744; called by muse, mutect2, varscan2
- PDE3A | c.2035A>G p.M679V | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.293); catalogued as COSV100761555; called by muse, mutect2, varscan2
- PFKFB1 | c.73A>T p.S25C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | PolyPhen benign (0); catalogued as COSV100895573; called by muse, mutect2, varscan2
- PLA2G6 | c.2135G>A p.S712N | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV59269721; called by muse, mutect2, varscan2
- PNLDC1 | c.243T>A p.Y81* | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99277085; called by muse, mutect2
- PRDM5 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1404353797, COSV53356294; called by muse, mutect2, varscan2
- PTPRC | c.3645C>T p.F1215= | Splice Region (SNP) | VAF 42/154 reads (27%) | catalogued as rs1558042118, COSV61407374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAPGEF1 | c.2945T>C p.I982T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480857489, COSV100940218; called by muse, mutect2, varscan2
- RBM22 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs1199923311, COSV99555889; called by muse, mutect2, varscan2
- RELT | c.644G>C p.R215P | Missense Mutation (SNP) | VAF 152/832 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.162); catalogued as COSV99292622; called by muse, varscan2
- SEC16B | c.1706T>C p.M569T | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as rs889765531, COSV100381157; called by muse, mutect2
- SH2D5 | c.949G>A p.A317T (on ENST00000444387 / NM_001103161.2; = p.A233T on NM_001103160.2) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV56121874, COSV99928375; called by muse, mutect2
- SUGP1 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV99894432; called by muse, mutect2, varscan2
- TAOK3 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 48/60 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV101183386, COSV66827514; called by muse, mutect2, varscan2
- TOX | c.78C>G p.C26W | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV100812540; called by muse, mutect2, varscan2
- TRPM2 | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV100308084; called by muse, mutect2, varscan2
- USP38 | c.2940A>G p.I980M | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100189039; called by muse, mutect2
- USP6 | c.2137A>G p.M713V | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.361); catalogued as rs770763434, COSV100002839; called by muse, mutect2, varscan2
- ZC4H2 | c.551C>A p.P184Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62004403; called by muse, mutect2, varscan2
- ZDBF2 | c.6899G>A p.R2300H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs760923997, COSV100984292, COSV100984476; called by muse, mutect2, varscan2
- ZNF391 | c.731C>A p.T244N | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99772367; called by muse, mutect2, varscan2
- AMPH | c.1291_1292del p.P431Tfs*28 | Frame Shift Del (DEL) | VAF 25/75 reads (33%) | called by pindel*, varscan2
- NEDD9 | c.1604_1611del p.A535Gfs*4 | Frame Shift Del (DEL) | VAF 34/194 reads (18%) | called by mutect2, pindel, varscan2
- OCRL | c.2032dup p.S678Kfs*48 | Frame Shift Ins (INS) | VAF 50/77 reads (65%) | called by mutect2, pindel, varscan2
- DNAH9 | c.7752C>T p.I2584= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as COSV99303447; called by muse, mutect2, varscan2
- DNAH9 | c.7890C>T p.I2630= | Silent (SNP) | VAF 166/356 reads (47%) | catalogued as rs769517411, COSV99303453; called by muse, varscan2
- DNAH9 | c.8031C>T p.F2677= | Silent (SNP) | VAF 126/257 reads (49%) | catalogued as rs1479330984, COSV52360454; called by muse, mutect2, varscan2
- EPPK1 | c.4128G>A p.Q1376= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as rs551138426, COSV101599720; called by muse, mutect2, varscan2
- FAM120A | c.1527C>T p.A509= | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV99464288; called by muse, varscan2
- FAM120A | c.1593C>T p.C531= | Silent (SNP) | VAF 34/50 reads (68%) | catalogued as COSV99464296; called by muse, varscan2
- GPR157 | c.837C>T p.F279= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs372777017; called by muse, mutect2
- PRAMEF18 | c.333T>C p.N111= | Silent (SNP) | VAF 42/196 reads (21%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.333T>C p.N111= | Silent (SNP) | VAF 132/906 reads (15%) | called by muse, mutect2, varscan2
- PTPRD | c.4311G>A p.G1437= | Silent (SNP) | VAF 66/77 reads (86%) | catalogued as rs1251038630, COSV100642788; called by muse, mutect2, varscan2
- RAG1 | c.2718A>C p.P906= | Silent (SNP) | VAF 118/123 reads (96%) | catalogued as COSV100200607; called by muse, mutect2, varscan2
- SUGP1 | c.636G>A p.E212= | Silent (SNP) | VAF 101/346 reads (29%) | catalogued as COSV99894436; called by muse, mutect2, varscan2
- TCF20 | c.5082G>A p.V1694= | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as rs1324348625, COSV100166573, COSV59497687; called by muse, mutect2, varscan2
- ZNF441 | c.1596G>A p.K532= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV100777381; called by muse, mutect2, varscan2
- COPS9 | chr2:240129973 G>A | 3'Flank (SNP) | VAF 25/29 reads (86%) | catalogued as rs765933574, COSV100216903; called by muse, mutect2, varscan2
- LTB4R | c.-263_-260del | 5'UTR (DEL) | VAF 28/66 reads (42%) | called by mutect2, pindel, varscan2
